Gene-level copy-number profile of tumor specimen TCGA-VQ-A91N-01A from TCGA case TCGA-VQ-A91N, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 59.6 years (21,753 days).
Specimen TCGA-VQ-A91N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.80a91a84-ea1f-456d-8e36-f556ebba433c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/54bf4bcc-6f7a-4f53-9a62-970952135282

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 295; copy number 1: 14,191; copy number 2: 30,531; copy number 3: 8,856; copy number 4: 4,346; copy number 5: 450; copy number 6: 485; copy number 7: 105; copy number 8: 8; copy number 9: 33; copy number 10: 100; copy number 11: 201; copy number 12: 20; copy number 13: 53; copy number 14: 31; copy number 15: 16; copy number 17: 4; copy number 19: 46; copy number 21: 27; copy number 22: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91N-01A-11D-A40Z-01): tumor purity 0.46, ploidy 4.95, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 159 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,809,269–59,811,310, 1 gene: AC093418.1.
- chr3:62,779,176–63,125,062, 5 genes (within-gene range 0–1): AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698.
- chr3:175,079,307–175,115,242, 1 gene (within-gene range 0–2): NAALADL2-AS3.
- chr4:91,108,023–91,325,306, 2 genes: AC004054.1, AC074124.1.
- chr4:151,102,751–151,325,605, 1 gene (within-gene range 0–1): SH3D19.
- chr4:151,259,503–151,891,263, 13 genes: AC104819.1, PRSS48, AC104819.2, RNU6-1282P, AC104819.3, FAM160A1-DT, FAM160A1, RN7SKP35, GATB, AC092611.1, AC107074.1, AC112242.2, AC112242.1.
- chr4:179,856,853–179,857,581, 1 gene: AC021193.1.
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr14:44,507,385–44,567,467, 1 gene (within-gene range 0–2): AL356022.1.
- chr14:67,533,290–67,600,286, 2 genes (within-gene range 0–2): PLEKHH1, PIGH.
- chr21:14,108,813–24,321,377, 130 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,587 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,364,304–151,583,583, 10 genes, copy number 5 (within-gene range 3–5): SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1.
- chr1:164,343,005–179,271,266, 302 genes, copy number 5–6 (broad region; genes not listed).
- chr1:234,811,052–234,932,653, 1 gene, copy number 7 (within-gene range 4–7): AL391832.4.
- chr1:234,904,186–235,104,609, 7 genes, copy number 7: RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2.
- chr2:174,011,856–175,184,607, 35 genes, copy number 6: AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14.
- chr2:179,934,401–198,572,581, 218 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr3:8,501,807–17,205,165, 204 genes, copy number 6 (broad region; genes not listed).
- chr3:17,333,126–17,465,510, 2 genes, copy number 6: AC090960.1, AC140076.1.
- chr3:42,782,908–43,999,149, 25 genes, copy number 6 (within-gene range 2–6): HIGD1A, AC099329.1, ACKR2, AC099329.2, AC092042.3, KRBOX1, CYP8B1, HNRNPA1P22, ZNF662, KRBOX1-AS1, GASK1A, AC092042.2, POMGNT2, AC092042.1, AC092042.4, SNRK, RN7SL517P, SNRK-AS1, ANO10, Y_RNA, AC097638.1, ABHD5, AC006055.1, AC006058.2, AC006058.3.
- chr3:84,958,989–87,324,723, 18 genes, copy number 5–6 (within-gene range 4–6): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25.
- chr5:40,512,333–40,798,374, 5 genes, copy number 8: TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1.
- chr5:154,887,411–155,018,141, 4 genes, copy number 6 (within-gene range 3–6): GEMIN5, MRPL22, AC008410.1, KIF4B.
- chr8:6,924,697–6,969,113, 6 genes, copy number 5: DEFA6, AF233439.1, DEFA4, DEFA8P, DEFA9P, DEFA10P.
- chr8:10,839,964–11,267,865, 13 genes, copy number 9 (within-gene range 2–9): AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13.
- chr8:19,901,717–20,700,152, 12 genes, copy number 7–9 (within-gene range 7–18): LPL, AC100802.1, RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1, AC022559.1, AC018541.1.
- chr8:69,922,751–71,228,629, 25 genes, copy number 5: RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1.
- chr8:90,592,804–91,398,155, 16 genes, copy number 15 (within-gene range 4–15): LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:92,668,660–93,700,433, 16 genes, copy number 13–17 (within-gene range 4–17): AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1.
- chr8:94,487,689–95,156,685, 29 genes, copy number 14 (within-gene range 4–14): VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2.
- chr8:95,206,876–95,269,201, 2 genes, copy number 14: LINC01298, C8orf37.
- chr8:97,772,313–97,865,485, 6 genes, copy number 6: Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1.
- chr8:131,432,776–132,481,095, 7 genes, copy number 5 (within-gene range 4–5): SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3.
- chr10:21,340,233–21,526,368, 8 genes, copy number 9: LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915, SKIDA1.
- chr10:21,526,568–21,564,577, 2 genes, copy number 9: AL358780.1, RNU6-306P.
- chr10:61,406,642–63,658,521, 32 genes, copy number 6–10: TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1.
- chr10:65,248,032–65,880,289, 3 genes, copy number 12: AL513321.1, AL592466.1, LINC01515.
- chr10:70,927,055–75,431,588, 139 genes, copy number 8–22 (broad region; genes not listed).
- chr10:75,450,081–75,743,755, 5 genes, copy number 12: AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr10:77,776,951–78,178,186, 13 genes, copy number 7: RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1.
- chr10:104,031,286–104,624,795, 16 genes, copy number 11 (within-gene range 2–11): COL17A1, MIR936, SFR1, CFAP43, MIR609, GSTO1, MIR4482, GSTO2, ITPRIP, AL162742.1, AL162742.2, ITPRIP-AS1, CFAP58-DT, CFAP58, LINC02620, AL161646.1.
- chr10:104,664,608–104,666,200, 1 gene, copy number 11: SORCS3-AS1.
- chr10:126,779,702–126,779,774, 1 gene, copy number 10: AL512272.1.
- chr10:126,988,095–127,026,507, 2 genes, copy number 10 (within-gene range 2–10): AL359094.1, AL359094.2.
- chr12:21,797,401–21,942,529, 2 genes, copy number 11 (within-gene range 4–11): ABCC9, AC008250.1.
- chr12:22,008,348–28,581,511, 116 genes, copy number 11–19 (within-gene range 2–19) (broad region; genes not listed).
- chr12:30,200,983–32,993,754, 85 genes, copy number 5–6 (broad region; genes not listed).
- chr18:20,946,906–22,228,029, 37 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2.
- chr18:28,146,233–33,751,195, 72 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:27,638,483–30,228,715, 63 genes, copy number 11 (broad region; genes not listed).
- chr20:20,659,710–21,535,665, 25 genes, copy number 5–7: EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2.

Autosomal genes at a single copy (total copy number 1): 12,419. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
